Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A20T, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A20T-01A (Primary Tumor).

[page 1 of 2]
100-0-3

Carcinoma, urothelial 8/20/3

Site: bladder, anterior wall C67.3

for 4/17/11

PATIENT HISTORY:

-year-old-man with detrusor muscle-invasive, high-grade urothelial carcinoma.
prostatic involvement.

PRE-OP DIAGNOSIS: Bladder cancer.

POST-OP DIAGNOSIS: Not given.

PROCEDURE: Radical cystoprostatectomy with construction of orthotopic neobladder.

with bladder base and possible

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -

THREE BENIGN LYMPH NODES (0/3). NEGATIVE FOR MALIGNANCY (0/3).

Collection Date:

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -

TWO BENIGN LYMPH NODES (0/2). NEGATIVE FOR MALIGNANCY (0/2).

PART 3: RIGHT URETER, MARGIN, SHAVE BIOPSY -

A. SEGMENT OF BENIGN URETER.

B. NEGATIVE FOR NEOPLASIA.

PART 4: LEFT URETER, MARGIN, SHAVE BIOPSY -

A. SEGMENT OF BENIGN URETER.

B. NEGATIVE FOR NEOPLASIA.

PART 5: URINARY BLADDER, DISTAL URETERS, BILATERAL URETERS, PROSTATE, BILATERAL SEMINAL VESICLES, AND VAS DEFERENTIA, RADICAL CYSTOPROSTATECTOMY -

URINARY BLADDER AND DISTAL URETERS:

- A. ULCERATED, INVASIVE UROTHELIAL CARCINOMA, HIGH-GRADE (2004 WHO/ISUP), PRESENT ON THE RIGHT ANTERIOR WALL OF THE URINARY BLADDER. CARCINOMA INFILTRATES THROUGH THE MUSCULARIS PROPRIA WITH EXTENSION (GROSSLY EVIDENT) INTO THE PERIVESICAL ADIPOSE TISSUE.
- B. MAXIMAL TUMOR DIAMETER IS 2.1 CM.
- C. RARE PERINEURAL INVASION IS PRESENT (SLIDE 5AA).
- D. PRESUMED CARCINOMATOUS ANGIOLYMPHATIC INVASION IS PRESENT, BUT NOT IDENTIFIED HISTOLOGICALLY (SEE DIAGNOSIS F).
- E. MULTIFOCAL, EXTENSIVE, FLAT UROTHELIAL CARCINOMA IN-SITU IS PRESENT WITHIN THE URINARY BLADDER AND PROSTATIC URETHRA.
- F. MICROSCOPIC FOCUS OF METASTATIC UROTHELIAL CARCINOMA IS PRESENT IN ONE PERIVESICAL LYMPH NODE (1/1) (SLIDE 5Z). THE METASTATIC FOCUS MEASURES 0.2 CM AND IS CONFINED TO THE LYMPH NODE, WITH NO EXTRACAPSULAR EXTENSION IDENTIFIED.
- G. TNM PATHOLOGIC STAGE (UROTHELIAL CARCINOMA): T3b, N1, MX.
- H. HISTOLOGIC GRADE: G3 (SEE SYNOPTIC).

PROSTATE, BILATERAL SEMINAL VESICLES, AND DISTAL VASA DEFERENTIA:

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3 + 4 = 7 (SLIDES 5P, 5Q, 5DD, 5FF, 5JJ). GLEASON PATTERN 4 COMPONENT COMPRISES APPROXIMATELY 40% OF THE PROSTATE CARCINOMA VOLUME (SLIDES 5P, 5Q).
- B. PROSTATIC CARCINOMA IS PRESENT, LIMITED TO THE RIGHT LOBE OF THE PROSTATE GLAND.
- C. GREATEST NODULAR DIAMETER OF THE PROSTATIC ADENOCARCINOMA IS 0.6 CM, INVOLVING LESS THAN 5% OF THE SAMPLED PROSTATE GLAND VOLUME.
- D. PROSTATE CARCINOMA IS CONFINED TO THE PROSTATE GLAND, WITHOUT EXTRACAPSULAR EXTENSION NOR INVOLVEMENT OF THE URINARY BLADDER.
- E. BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA ARE FREE OF NEOPLASIA.
- F. FOCAL PERINEURAL INVASION BY PROSTATIC ADENOCARCINOMA IS IDENTIFIED (SLIDE 5Q).
- G. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- H. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (HGPIN) IS PRESENT.
- I. INTRADUCTAL UROTHELIAL CARCINOMA IS PRESENT IN THE PROSTATE IN PERIURETHRAL DUCTS IN CONTINUITY WITH URETHRAL FLAT UROTHELIAL CARCINOMA IN-SITU (SLIDES 5B, 5C, 5DD, 5GG).
- J. TNM PATHOLOGIC STAGE (PROSTATIC ADENOCARCINOMA): T2a, N0, MX.
- K. HISTOLOGIC GRADE: G3-4 (SEE SYNOPTIC).

Case is [] ()		

[page 2 of 2]
SYNOPTIC DATA - PRIMARY URINARY BLADDER TUMORS

SPECIMEN TYPE: Radical cystoprostatectomy
TUMOR SITE: Anterior wall
TUMOR SIZE: Greatest dimension: 2.1 cm
Additional dimensions: 1.5 X 1.2 cm
HISTOLOGIC TYPE: Urothelial (transitional cell) carcinoma
ASSOCIATED EPITHELIAL LESIONS: None identified
HISTOLOGIC GRADE: Urothelial carcinoma - High-grade
TUMOR CONFIGURATION: Ulcerated
PATHOLOGIC STAGING (pTNM): pT3b
pN1
Number of nodes examined: 6
Number of nodes involved: 1
pMX

MARGINS: Margins uninvolved by invasive carcinoma
VENOUS/LYMPHATIC (LARGE/SMALL) VESSEL INVASION (V/L): Present
DIRECT EXTENSION OF INVASIVE TUMOR: Perivesical fat
ADDITIONAL PATHOLOGIC FINDINGS: Urothelial dysplasia (low-grade intraurothelial neoplasia)

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
PRIMARY GLEASON GRADE: 3
SECONDARY GLEASON GRADE: 4
GLEASON SUM SCORE: 7
GLEASON 4/5 PERCENTAGE: 40%
WEIGHT OF PROSTATE: 30gm
TUMOR SIZE: Maximum dimension: 0.6 cm
LOBE LATERALITY: Right Lobe
PERCENT OF SPECIMEN INVOLVED BY TUMOR: < 5% of specimen involved by invasive tumor
MULTIFOCAL DISEASE: No
HIGH GRADE PIN: Yes - multifocal
EXTRAPROSTATIC EXTENSION: No
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: No
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
LYMPH NODES EXAMINED: 6
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT2a
N STAGE, PATHOLOGIC: pNX
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G2, Moderately differentiated

Source: NCI Genomic Data Commons file 5a279bdc-23fc-42fb-a83e-cf6a2369a39d (TCGA-BT-A20T.6DCDDE73-580E-46FF-9A06-39A85EB4830A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).